Somatic mutation profile of tumor specimen TCGA-AZ-5407-01A (aliquot TCGA-AZ-5407-01A-01D-1719-10) from TCGA case TCGA-AZ-5407, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 51.5 years (18,820 days).
Specimen TCGA-AZ-5407-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abf99448-8d28-43c2-9b2e-94b65861c453.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-5407-10A (Blood Derived Normal), aliquot TCGA-AZ-5407-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09114c6f-a472-425b-94df-849c49406d07

The open-access MAF lists 104 somatic variants for this specimen: 79 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 22, Nonsense Mutation 8, Intron 2, Splice Site 2, RNA 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 98/283 reads (35%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 32/89 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 21/517 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC9 | c.4538C>A p.A1513E | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53988928; called by muse, mutect2, varscan2
- ACVR2A | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 16/174 reads (9%) | catalogued as COSV54018614; called by muse, mutect2, varscan2
- AHNAK2 | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 70/383 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV60933645; called by muse, mutect2, varscan2
- ANKRD11 | c.5136C>G p.C1712W | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV56374336; called by muse, mutect2, varscan2
- AP3D1 | c.3056G>A p.G1019E | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61433597; called by muse, mutect2
- APC | c.3850G>T p.E1284* | Nonsense Mutation (SNP) | VAF 70/206 reads (34%) | catalogued as COSV57324438, COSV57388721; called by muse, mutect2, varscan2
- APC | c.4588G>T p.E1530* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as CD086048, CM040981, COSV57335138, COSV57368616; called by muse, mutect2, varscan2
- ARHGAP33 | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 137/511 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs755309814, COSV50135707; called by muse, mutect2, varscan2
- ATP7A | c.4432G>A p.V1478I | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV58455702; called by muse, mutect2, varscan2
- BRWD3 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 94/289 reads (33%) | catalogued as COSV64748961, COSV64754484; called by muse, mutect2, varscan2
- BRWD3 | c.1233-1G>T p.X411_splice | Splice Site (SNP) | VAF 48/210 reads (23%) | catalogued as COSV64754486; called by muse, mutect2, varscan2
- CABP1 | c.787G>A p.E263K (on ENST00000316803 / NM_001033677.1; = p.E60K on NM_004276.5) | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56460762; called by muse, mutect2, varscan2
- CACNA1D | c.5801A>G p.Q1934R (on ENST00000350061 / NM_001128840.3; = p.Q1954R on NM_000720.4) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.131); catalogued as COSV55467912; called by muse, mutect2, varscan2
- CACNA1H | c.6850G>A p.G2284S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs200706031, COSV99326804; called by muse, mutect2, varscan2
- CCNB2 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55596815; called by muse, mutect2, varscan2
- CDH13 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs760476515, COSV51876564; called by muse, mutect2, varscan2
- CDH6 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 7/204 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1474061884; called by muse, mutect2
- CELF4 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs372830155; called by muse, mutect2, varscan2
- DUSP26 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 148/460 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs545078102, COSV56362697; called by muse, mutect2, varscan2
- ESPN | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs1223188180, COSV64705581; called by muse, mutect2
- FAM47B | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs770232500, COSV61453452; called by muse, mutect2, varscan2
- FARP1 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 123/340 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1265266786, COSV60342023; called by muse, mutect2, varscan2
- FBXO47 | c.569T>A p.L190Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV65243034; called by muse, mutect2, varscan2
- FBXO47 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV65242926, COSV65243039; called by muse, mutect2, varscan2
- GJB5 | c.567C>A p.F189L | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV58357253; called by muse, mutect2, varscan2
- GLB1L3 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs932591769, COSV68393574, COSV68393584; called by muse, mutect2, varscan2
- GPR171 | c.465A>T p.K155N | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV56400713; called by muse, mutect2, varscan2
- GUCY2D | c.2418G>T p.K806N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV54699451; called by muse, mutect2, varscan2
- HEPHL1 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs200108606, COSV59890083; called by muse, mutect2, varscan2
- IQCN | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs756118445, COSV101148997, COSV66578923; called by muse, mutect2, varscan2
- KRT1 | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 212/1280 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.351); catalogued as COSV52870054; called by muse, mutect2, varscan2
- KRT3 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.17); catalogued as COSV58816907, COSV58817635; called by muse, mutect2, varscan2
- MUC17 | c.9097G>A p.G3033S | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.246); catalogued as rs753938085, COSV60296542, COSV60306858; called by muse, mutect2, varscan2
- NCAM1 | c.2365G>A p.V789M (on ENST00000316851 / NM_181351.5; = p.V779M on NM_000615.7) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868908758, COSV57526699; called by muse, mutect2, varscan2
- NCOA5 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764153135, COSV51648018; called by muse, mutect2, varscan2
- NDUFA11 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV99399051; called by muse, mutect2
- NKX6-1 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); catalogued as COSV55684321; called by muse, mutect2
- OTOGL | c.6142C>A p.P2048T (on ENST00000547103; = p.P2039T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV54025317; called by muse, mutect2, varscan2
- PCIF1 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 50/153 reads (33%) | catalogued as rs1180325013, COSV65027389; called by muse, mutect2, varscan2
- PDE2A | c.2722C>T p.P908S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV57815129; called by muse, mutect2, varscan2
- PDE8B | c.1786A>T p.T596S | Missense Mutation (SNP) | VAF 158/437 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV53739446, COSV53747201; called by muse, mutect2, varscan2
- PLEK2 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as rs1380595756, COSV53605484; called by muse, mutect2, varscan2
- POLR2B | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108427; called by muse, mutect2
- POU3F4 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV100937195, COSV64541522; called by muse, mutect2, varscan2
- PRKCG | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV54726444; called by muse, mutect2
- RALYL | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs749865840, COSV72819608; called by muse, mutect2, varscan2
- RBM26 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs377752187; called by muse, mutect2, varscan2
- RELN | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 167/367 reads (46%) | catalogued as COSV100635150, COSV59034599; called by muse, mutect2, varscan2
- REM1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199660041, COSV52427586; called by muse, mutect2, varscan2
- RNF213 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.824); catalogued as rs149686155; called by muse, mutect2, varscan2
- RPA1 | c.1749C>T p.D583= | Splice Region (SNP) | VAF 52/208 reads (25%) | catalogued as rs879302106, COSV54614140; called by muse, mutect2, varscan2
- RPS6KA2 | c.2192C>T p.T731M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55832153; called by muse, mutect2
- SF3B2 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV59430510; called by muse, mutect2, varscan2
- SOHLH2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58523829; called by muse, mutect2
- SPTBN1 | c.4387G>A p.V1463M | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs201812651, COSV61693776; called by muse, mutect2, varscan2
- TAL1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs767980860, COSV53749056, COSV99595866; called by muse, mutect2, varscan2
- TBX4 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as rs749007884, COSV53610282; called by muse, mutect2, varscan2
- TEKT5 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 106/304 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs201580847, COSV51587897; called by muse, mutect2, varscan2
- TGOLN2 | c.211A>T p.S71C | Missense Mutation (SNP) | VAF 119/528 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV56407830; called by muse, mutect2, varscan2
- TLX2 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99283816; called by muse, mutect2
- TMEM151A | c.1393C>A p.Q465K | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.075); catalogued as COSV59175647; called by muse, mutect2, varscan2
- TNC | c.3958A>C p.T1320P | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745899976, COSV60791668; called by muse, mutect2, varscan2
- USP21 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV99237622; called by muse, mutect2
- UTP18 | c.233T>G p.L78R | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV56585595; called by muse, mutect2
- VPS53 | c.6G>T p.M2I | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.38); catalogued as COSV52139563; called by muse, mutect2, varscan2
- VPS53 | c.5T>G p.M2R | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV52139587; called by muse, mutect2, varscan2
- XYLB | c.1338A>T p.R446S | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV52916461; called by muse, mutect2, varscan2
- ZFP64 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 98/264 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV53804665; called by muse, mutect2, varscan2
- ZMYND8 | c.2770G>A p.A924T (on ENST00000311275 / NM_001363741.2; = p.A898T on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/295 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs371544404; called by muse, mutect2, varscan2
- ZNF536 | c.1135G>A p.G379S | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs200416337, COSV62836242; called by muse, mutect2, varscan2
- ZNF550 | c.61T>C p.F21L | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57307967; called by muse, mutect2, varscan2
- ZNF862 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 125/208 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs748305753, COSV56222729; called by muse, mutect2, varscan2
- AXIN2 | c.956_956+8del p.X319_splice | Splice Site (DEL) | VAF 34/120 reads (28%) | called by mutect2, pindel, varscan2
- NRK | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF835 | c.786_788del p.S263del | In Frame Del (DEL) | VAF 201/370 reads (54%) | called by pindel, varscan2
- ADAMTS9 | c.5739G>T p.G1913= | Silent (SNP) | VAF 53/153 reads (35%) | catalogued as COSV55792592; called by muse, mutect2, varscan2
- ATP8B4 | c.1173C>T p.S391= | Silent (SNP) | VAF 83/209 reads (40%) | catalogued as rs770476015, COSV52710285, COSV99464462; called by muse, mutect2, varscan2
- DEF8 | c.324G>A p.L108= (on ENST00000268676 / NM_207514.3; = p.L47= on NM_017702.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV51921409; called by mutect2, varscan2
- DNMT3A | c.2397C>T p.P799= | Silent (SNP) | VAF 9/171 reads (5%) | catalogued as rs886148050, COSV99263743, COSV99265173; called by muse, mutect2
- DOHH | c.237A>G p.Q79= | Silent (SNP) | VAF 39/292 reads (13%) | catalogued as COSV51746245; called by muse, mutect2, varscan2
- GBP5 | c.210G>A p.T70= | Silent (SNP) | VAF 95/223 reads (43%) | catalogued as rs138919870; called by muse, mutect2, varscan2
- GTF2F1 | c.792G>A p.G264= | Silent (SNP) | VAF 52/464 reads (11%) | catalogued as COSV66727338; called by muse, mutect2, varscan2
- IQCN | c.2838C>A p.I946= | Silent (SNP) | VAF 79/149 reads (53%) | catalogued as COSV62748854; called by muse, mutect2, varscan2
- ITGB3 | c.555G>A p.K185= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as COSV71385358; called by muse, mutect2, varscan2
- KCNA5 | c.582C>T p.D194= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as COSV52909242; called by muse, mutect2, varscan2
- MFAP1 | c.36C>G p.P12= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as COSV51041918; called by muse, mutect2, varscan2
- MTNR1A | c.309T>C p.S103= | Silent (SNP) | VAF 82/183 reads (45%) | catalogued as COSV56158286; called by muse, mutect2, varscan2
- OR6X1 | c.363C>T p.Y121= | Silent (SNP) | VAF 25/165 reads (15%) | catalogued as COSV60010604; called by muse, mutect2, varscan2
- P2RY2 | c.846C>T p.N282= | Silent (SNP) | VAF 70/166 reads (42%) | catalogued as COSV60778095; called by muse, mutect2, varscan2
- PLEKHG7 | c.1905C>T p.H635= | Silent (SNP) | VAF 77/202 reads (38%) | catalogued as rs554372058, COSV59290596; called by muse, mutect2, varscan2
- PTPN20 | c.618G>A p.K206= | Silent (SNP) | VAF 91/861 reads (11%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.198C>A p.I66= | Silent (SNP) | VAF 86/803 reads (11%) | catalogued as COSV99708029; called by muse, mutect2, varscan2
- SOHLH1 | c.555G>A p.A185= | Silent (SNP) | VAF 103/270 reads (38%) | catalogued as rs776969611, COSV53680720; called by muse, mutect2, varscan2
- SULT1A2 | c.393C>T p.N131= | Silent (SNP) | VAF 44/339 reads (13%) | catalogued as rs139054845; called by muse, mutect2, varscan2
- TAGAP | c.2079G>A p.P693= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as rs147907532; called by muse, mutect2, varscan2
- TBK1 | c.1797G>A p.T599= | Silent (SNP) | VAF 50/175 reads (29%) | catalogued as rs758803587, COSV59158841; called by muse, mutect2, varscan2
- TRIM71 | c.2370C>A p.G790= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV67472930; called by muse, mutect2, varscan2
- ERCC6 | c.1397+8680G>A | Intron (SNP) | VAF 13/123 reads (11%) | catalogued as rs375175948, CM159750; called by muse, mutect2, varscan2
- TMBIM6 | c.-31+560A>T | Intron (SNP) | VAF 27/162 reads (17%) | catalogued as COSV57281358; called by muse, varscan2
- TMEM183B | n.1025G>T | RNA (SNP) | VAF 234/829 reads (28%) | called by muse, mutect2, varscan2
